Somatic mutation profile of tumor specimen TCGA-A5-A0GU-01A (aliquot TCGA-A5-A0GU-01A-11W-A062-09) from TCGA case TCGA-A5-A0GU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 58.0 years (21,192 days).
Specimen TCGA-A5-A0GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 824d83c2-d6d9-44f2-a133-9fa0a4ced8bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GU-10A (Blood Derived Normal), aliquot TCGA-A5-A0GU-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08065205-50ce-401e-94d7-8de53ad7dcd8

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, RNA 2, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 92/182 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs991636648, COSV54640174; called by muse, mutect2, varscan2
- ARFGEF2 | c.4831C>G p.L1611V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64215074; called by muse, mutect2, varscan2
- ARID5B | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1178738385, COSV54429709; called by muse, mutect2, varscan2
- ATP7A | c.2843T>C p.V948A | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV58453806; called by muse, mutect2, varscan2
- BCL2L11 | c.526G>A p.E176K (on ENST00000393256 / NM_138621.5; = p.E116K on NM_006538.5) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.054); catalogued as rs1170116948, COSV58029750; called by muse, mutect2, varscan2
- CASP6 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV54461972; called by muse, mutect2, varscan2
- COCH | c.1382C>T p.T461I (on ENST00000216361 / NM_001347720.1; = p.T396I on NM_004086.3) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV53549840, COSV53553047; called by muse, mutect2, varscan2
- COL4A4 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs536570392, COSV61631223; called by muse, mutect2, varscan2
- CYP4F2 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV50002839; called by muse, mutect2, varscan2
- FNBP4 | c.2093C>G p.S698* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as COSV55452141; called by muse, mutect2, varscan2
- HIF1A | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60191722; called by muse, mutect2, varscan2
- IGFBPL1 | c.531A>C p.E177D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV66618628; called by muse, mutect2, varscan2
- ITIH6 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs774718756, COSV54487256; called by muse, mutect2, varscan2
- KCND2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576011; called by muse, mutect2, varscan2
- KCNQ3 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs746403693, COSV66480722; called by muse, mutect2, varscan2
- MED4 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51640534; called by muse, mutect2, varscan2
- NAMPT | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55996733; called by muse, mutect2, varscan2
- NDUFA8 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV65653685; called by muse, mutect2, varscan2
- OR5M11 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV73142011; called by muse, mutect2, varscan2
- PCSK1 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs567748971, COSV60735982; called by muse, mutect2, varscan2
- PTEN | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64288997, COSV64289799, COSV64297500; called by muse, mutect2, varscan2
- RUFY2 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61192388; called by muse, mutect2, varscan2
- SDAD1 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs753203729, COSV62403820; called by muse, mutect2, varscan2
- SHBG | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV52647875; called by mutect2, varscan2
- SSX1 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV65356391; called by muse, mutect2, varscan2
- STEAP3 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV61529277; called by muse, mutect2
- SWSAP1 | c.284T>G p.L95R (on ENST00000312423; = p.L116R on NM_175871.4) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55801583; called by muse, mutect2, varscan2
- TSPAN6 | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV65957573; called by muse, mutect2, varscan2
- TTN | c.51231G>A p.W17077* (on ENST00000591111; = p.W9653* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV60345978; called by muse, mutect2, varscan2
- WDR44 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as COSV54169013; called by muse, mutect2
- ZNF281 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV54169851; called by muse, mutect2, varscan2
- ZNF440 | c.922A>T p.R308W | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58372493; called by muse, mutect2, varscan2
- CASP1 | c.4del p.A2Pfs*5 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1722_1745+5del p.X574_splice (on ENST00000521381 / NM_181523.3; = p.X304_splice on NM_181504.4) | Splice Site (DEL) | VAF 18/82 reads (22%) | called by pindel, varscan2
- PIK3R1 | c.1770dup p.Q591Afs*11 (on ENST00000521381 / NM_181523.3; = p.Q321Afs*11 on NM_181504.4) | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | called by pindel, varscan2
- PTEN | c.797_801dup p.D268Kfs*10 | Frame Shift Ins (INS) | VAF 33/153 reads (22%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATP2A2 | c.2401C>T p.L801= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV57876332; called by muse, mutect2, varscan2
- CPA6 | c.999C>T p.P333= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs150477940; called by muse, mutect2, varscan2
- FYB2 | c.1404T>G p.V468= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV58589260; called by muse, mutect2, varscan2
- LDOC1 | c.45G>A p.R15= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV65159699; called by muse, varscan2
- SAMD9L | c.2244C>T p.T748= | Silent (SNP) | VAF 45/267 reads (17%) | catalogued as COSV59085288; called by muse, mutect2, varscan2
- TEX2 | c.1314G>A p.K438= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV51985561; called by muse, mutect2, varscan2
- TMEM132D | c.1698C>T p.R566= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs757029767, COSV67160902; called by muse, mutect2, varscan2
- TRIML1 | c.717G>A p.S239= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs780369509, COSV60196865; called by muse, mutect2, varscan2
- URGCP | c.1281C>T p.F427= (on ENST00000453200 / NM_001077663.3; = p.F418= on NM_017920.4) | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs17172256, COSV56252671; called by muse, mutect2, varscan2
- CLCA3P | n.104A>T | RNA (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- SNORD116-1 | n.71G>A | RNA (SNP) | VAF 17/43 reads (40%) | catalogued as rs756550049; called by muse, mutect2, varscan2
